MMRF case MMRF_2840 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/eae9660c-d69b-4556-9e5a-1f6e7ec4bbb0

Demographics
Sex at birth: male; Age at index: 59 years; Vital status: Dead; Days to death: 25 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.5 years (21,749 days); ISS stage: II; Days to last known disease status: 25 days; Days to last follow up: 25 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 1, day 25.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- M Protein 6.13 g/dL.
- Platelets 145 ×10⁹/L.
- Calcium 2.88 mmol/L.
- Hemoglobin 6.2 mmol/L.
- Creatinine 324 µmol/L.
- Lactate Dehydrogenase 10 µkat/L.
- Beta 2 Microglobulin 4.4 µg/mL.
- Absolute Neutrophil 2.71 ×10⁹/L.
- Albumin 31 g/L.

Other clinical attributes
- Day 1: Weight: 72 kg; Height: 175 cm.

Biospecimens (2 samples)
- Sample MMRF_2840_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2840_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
